Somatic mutation profile of tumor specimen 0DVKE9 from CCDI case PBCMXB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (754 days).
Specimen 0DVKE9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 363e15e3-15ae-4f73-957c-75da77d961b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVKEH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c33d4919-f256-4687-9609-548d88bdaf1d

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPI | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 73/773 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs148548669, COSV62894541; called by muse, mutect2
- GRIN2A | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 309/634 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747198986, COSV58031994; called by muse, mutect2, varscan2
- LMCD1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 97/849 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440912941, COSV50088926; called by muse, mutect2, varscan2
- MAP3K21 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 71/770 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs750067830, COSV64042176; called by muse, mutect2
- MICAL3 | c.5363G>A p.R1788Q | Missense Mutation (SNP) | VAF 174/433 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.728); catalogued as rs888455219; called by muse, mutect2, varscan2
- PRPH2 | c.659G>C p.R220P | Missense Mutation (SNP) | VAF 178/479 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM951120; called by muse, mutect2, varscan2
- SLC12A5 | c.1837C>T p.R613C (on ENST00000454036 / NM_001134771.2; = p.R590C on NM_020708.5) | Missense Mutation (SNP) | VAF 42/694 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54804588; called by muse, mutect2
- ENPP1 | c.1751A>G p.N584S | Missense Mutation (SNP) | VAF 280/780 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNB1 | c.5267C>T p.A1756V | Missense Mutation (SNP) | VAF 213/571 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GBF1 | c.1614G>A p.E538= (on ENST00000369983 / NM_001377137.1; = p.E537= on NM_004193.3) | Silent (SNP) | VAF 253/654 reads (39%) | called by muse, mutect2, varscan2
- OR4C16 | c.444G>T p.V148= | Silent (SNP) | VAF 378/804 reads (47%) | called by muse, mutect2, varscan2
- RASIP1 | c.1926G>A p.E642= | Silent (SNP) | VAF 235/564 reads (42%) | called by muse, mutect2, varscan2
- UGGT1 | c.4548C>T p.Y1516= | Silent (SNP) | VAF 500/1140 reads (44%) | catalogued as rs373943322; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- IL21R | c.-17+593G>A | Intron (SNP) | VAF 182/428 reads (43%) | catalogued as rs1293235843; called by muse, mutect2, varscan2
